Somatic mutation profile of tumor specimen MMRF_2170_1_BM_CD138pos (aliquot MMRF_2170_1_BM_CD138pos_T1_KHS5U_L08836) from MMRF case MMRF_2170, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 55.6 years (20,305 days).
Specimen MMRF_2170_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e583f8db-dc0c-4331-859a-523441898c40.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2170_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2170_1_PB_Whole_C3_KHS5U_L08775; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/80002d23-364d-4b52-99c1-d9c6f09d0065

The open-access MAF lists 118 somatic variants for this specimen: 52 protein-altering or splice-affecting, 10 silent, 56 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, 3'UTR 24, Intron 14, Silent 10, 5'UTR 9, 3'Flank 5, Frame Shift Del 4, 5'Flank 3, Nonsense Mutation 2, Splice Site 1, In Frame Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADARB2 | c.1886G>A p.R629H | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs377469652; called by muse, mutect2, varscan2
- CDHR1 | c.824G>A p.R275Q | Missense Mutation (SNP) | VAF 140/265 reads (53%) | SIFT tolerated (0.48); PolyPhen benign (0.028); catalogued as rs201505995, COSV60565872; called by muse, mutect2, varscan2
- CDKN2C | c.43del p.R15Gfs*4 | Frame Shift Del (DEL) | VAF 42/57 reads (74%) | catalogued as COSV52954294, COSV52955354, COSV52955909; called by mutect2, pindel, varscan2
- FAM222B | c.1049C>G p.S350C | Missense Mutation (SNP) | VAF 54/153 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.634); catalogued as rs750212243; called by muse, mutect2, varscan2
- KRAS | c.190T>G p.Y64D | Missense Mutation (SNP) | VAF 44/111 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55534434, COSV55579983, COSV55703886; called by muse, mutect2, varscan2
- MYH7 | c.2456G>A p.R819Q | Missense Mutation (SNP) | VAF 65/82 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs773009513, CM132339; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO1E | c.1782G>C p.K594N | Missense Mutation (SNP) | VAF 81/178 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as rs28660684; called by muse, mutect2, varscan2
- OR10V1 | c.389C>A p.P130H | Missense Mutation (SNP) | VAF 89/212 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772202040; called by muse, mutect2, varscan2
- RELN | c.74C>T p.A25V | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.07); catalogued as rs757957218; called by muse, mutect2
- RPH3AL | c.696C>G p.D232E | Missense Mutation (SNP) | VAF 82/178 reads (46%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV100046900; called by muse, mutect2, varscan2
- SLC1A7 | c.80T>C p.V27A | Missense Mutation (SNP) | VAF 91/125 reads (73%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs750855965; called by muse, mutect2, varscan2
- SLITRK5 | c.2219A>C p.K740T | Missense Mutation (SNP) | VAF 163/170 reads (96%) | SIFT tolerated (0.09); PolyPhen benign (0.351); catalogued as rs772275354; called by muse, mutect2, varscan2
- TNFRSF10B | c.554C>T p.T185I | Missense Mutation (SNP) | VAF 80/164 reads (49%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.893); catalogued as rs1216121356; called by muse, mutect2, varscan2
- ACAD10 | c.903C>A p.Y301* | Nonsense Mutation (SNP) | VAF 29/132 reads (22%) | called by muse, mutect2, varscan2
- ADAMTSL4 | c.520C>T p.H174Y | Missense Mutation (SNP) | VAF 467/677 reads (69%) | SIFT deleterious (0.01); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- ALS2 | c.3725G>C p.G1242A | Missense Mutation (SNP) | VAF 12/344 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2
- ANGPT1 | c.575+1G>C p.X192_splice | Splice Site (SNP) | VAF 28/55 reads (51%) | called by muse, mutect2, varscan2
- CAPN6 | c.964G>T p.E322* | Nonsense Mutation (SNP) | VAF 20/148 reads (14%) | called by muse, mutect2, varscan2
- CCDC102A | c.1424A>G p.D475G | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- CDH2 | c.1633A>C p.K545Q | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (0.43); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CEP192 | c.5264C>T p.S1755L | Missense Mutation (SNP) | VAF 10/240 reads (4%) | SIFT tolerated (0.26); PolyPhen benign (0.055); called by muse, mutect2
- DNAH9 | c.434T>C p.L145P | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by mutect2, varscan2
- DUSP2 | c.461del p.T154Kfs*87 | Frame Shift Del (DEL) | VAF 77/161 reads (48%) | called by mutect2, pindel*
- EEFSEC | c.37C>G p.L13V | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ERI1 | c.16A>G p.S6G | Missense Mutation (SNP) | VAF 47/115 reads (41%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- IGHV1-69D | c.236A>G p.Y79C | Missense Mutation (SNP) | VAF 106/108 reads (98%) | SIFT deleterious (0.01); PolyPhen benign (0.195); called by muse, varscan2
- IGHV1-69D | c.211A>T p.I71F | Missense Mutation (SNP) | VAF 89/90 reads (99%) | SIFT tolerated (0.5); PolyPhen benign (0.003); called by muse, varscan2
- IGLC2 | c.211T>C p.Y71H | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- INTS3 | c.1090C>A p.L364M | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- METTL21C | c.23C>T p.A8V | Missense Mutation (SNP) | VAF 92/92 reads (100%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- MSH2 | c.2531C>T p.A844V | Missense Mutation (SNP) | VAF 8/160 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MTMR2 | c.849_855delinsT p.C284_S285del | In Frame Del (DEL) | VAF 54/179 reads (30%) | called by pindel, varscan2*
- NTSR1 | c.637A>G p.S213G | Missense Mutation (SNP) | VAF 133/272 reads (49%) | SIFT tolerated (0.52); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PDE6B | c.1504T>C p.Y502H | Missense Mutation (SNP) | VAF 4/67 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.019); called by muse, mutect2
- PIK3CG | c.2786T>C p.V929A | Missense Mutation (SNP) | VAF 152/307 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- PROB1 | c.2479C>T p.P827S | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.595); called by muse, mutect2
- RBM20 | c.74G>A p.S25N | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ROBO1 | c.4508T>C p.V1503A | Missense Mutation (SNP) | VAF 100/239 reads (42%) | SIFT tolerated (0.96); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ROBO3 | c.1744A>C p.T582P | Missense Mutation (SNP) | VAF 55/123 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC16A9 | c.1067G>T p.G356V | Missense Mutation (SNP) | VAF 87/178 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC4A10 | c.2527G>A p.E843K (on ENST00000446997 / NM_001354461.2; = p.E813K on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/127 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2
- SLC9C1 | c.2655del p.A886Pfs*4 | Frame Shift Del (DEL) | VAF 52/136 reads (38%) | called by mutect2, pindel, varscan2
- SNTB1 | c.1406C>G p.P469R | Missense Mutation (SNP) | VAF 116/227 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SPIDR | c.845A>T p.H282L | Missense Mutation (SNP) | VAF 32/178 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- SPINK5 | c.2120G>A p.C707Y | Missense Mutation (SNP) | VAF 87/147 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- SVIL | c.2703C>G p.D901E (on ENST00000355867 / NM_021738.3; = p.D475E on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 125/252 reads (50%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TMEM131 | c.139C>G p.H47D | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.017); called by muse, mutect2
- TRAF3 | c.937_940del p.E313Pfs*9 | Frame Shift Del (DEL) | VAF 35/37 reads (95%) | called by mutect2, pindel, varscan2
- TTC6 | c.263C>A p.A88D | Missense Mutation (SNP) | VAF 13/140 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.144); called by muse, mutect2, varscan2
- UNC80 | c.1027T>C p.W343R | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- UNC80 | c.7278G>T p.Q2426H | Missense Mutation (SNP) | VAF 44/124 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, varscan2
- USHBP1 | c.1768T>A p.L590I | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- BTG1 | c.129C>T p.S43= | Silent (SNP) | VAF 26/60 reads (43%) | catalogued as rs1376032959, COSV55458531; called by muse, mutect2, varscan2
- CFAP410 | c.159C>T p.S53= | Silent (SNP) | VAF 48/130 reads (37%) | catalogued as rs753752452; called by muse, mutect2, varscan2
- CLSTN2 | c.1005A>G p.P335= | Silent (SNP) | VAF 12/275 reads (4%) | called by muse, mutect2
- ERCC2 | c.390C>T p.V130= | Silent (SNP) | VAF 62/144 reads (43%) | catalogued as rs757159764, COSV99676493; called by muse, mutect2, varscan2
- FABP7 | c.225T>A p.T75= | Silent (SNP) | VAF 40/110 reads (36%) | called by muse, mutect2, varscan2
- KRT76 | c.231G>T p.R77= | Silent (SNP) | VAF 107/226 reads (47%) | called by muse, mutect2, varscan2
- PCDH18 | c.1458T>A p.T486= | Silent (SNP) | VAF 151/154 reads (98%) | called by muse, mutect2, varscan2
- ROR2 | c.1179G>A p.S393= | Silent (SNP) | VAF 24/294 reads (8%) | catalogued as rs541919641, COSV65218014; called by muse, mutect2
- SSX1 | c.66C>T p.S22= | Silent (SNP) | VAF 91/93 reads (98%) | called by muse, mutect2, varscan2
- TNS1 | c.1860A>G p.Q620= | Silent (SNP) | VAF 156/335 reads (47%) | catalogued as rs185157555; called by muse, mutect2, varscan2
- ATP11AUN | n.2045G>A | RNA (SNP) | VAF 6/132 reads (5%) | called by muse, mutect2
- BCCIP | chr10:125841325 A>T | 3'Flank (SNP) | VAF 76/180 reads (42%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021364 T>C | 5'Flank (SNP) | VAF 92/185 reads (50%) | called by muse, mutect2, varscan2
- BMP6 | c.*906_*937del | 3'UTR (DEL) | VAF 45/110 reads (41%) | called by mutect2, pindel*
- CACYBP | c.*1016A>G | 3'UTR (SNP) | VAF 19/55 reads (35%) | catalogued as rs939821890; called by muse, mutect2, varscan2
- CDH9 | c.*144T>A | 3'UTR (SNP) | VAF 60/119 reads (50%) | called by muse, mutect2, varscan2
- CETN3 | c.*420C>A | 3'UTR (SNP) | VAF 68/153 reads (44%) | called by muse, mutect2, varscan2
- CYB561 | c.301+12G>A | Intron (SNP) | VAF 64/145 reads (44%) | called by muse, mutect2, varscan2
- DIPK2B | c.499-5470G>T | Intron (SNP) | VAF 13/34 reads (38%) | called by muse, mutect2, varscan2
- DTX1 | c.-366C>G | 5'UTR (SNP) | VAF 48/108 reads (44%) | called by muse, varscan2
- DTX1 | c.-365C>T | 5'UTR (SNP) | VAF 46/107 reads (43%) | called by muse, varscan2
- DTX1 | c.-351G>A | 5'UTR (SNP) | VAF 52/114 reads (46%) | catalogued as rs1442659524, COSV57495064, COSV57497913; called by muse, varscan2
- DTX1 | c.-136G>A | 5'UTR (SNP) | VAF 67/124 reads (54%) | called by muse, mutect2, varscan2
- ELF4 | c.*1733C>T | 3'UTR (SNP) | VAF 4/32 reads (13%) | catalogued as rs879152240; called by muse, mutect2, varscan2
- ETV1 | chr7:13893891 A>C | 3'Flank (SNP) | VAF 31/52 reads (60%) | catalogued as rs1163204384; called by muse, mutect2, varscan2
- FAM124B | c.732+955dup | Intron (INS) | VAF 23/153 reads (15%) | catalogued as rs983015203; called by mutect2, varscan2
- FZD1 | c.*365A>G | 3'UTR (SNP) | VAF 8/90 reads (9%) | called by muse, mutect2
- GAPDH | c.29+70G>A | Intron (SNP) | VAF 106/200 reads (53%) | called by muse, mutect2, varscan2
- GAS8 | c.1288-241C>T | Intron (SNP) | VAF 67/69 reads (97%) | called by muse, mutect2, varscan2
- GNAT3 | c.-31A>T | 5'UTR (SNP) | VAF 12/407 reads (3%) | called by muse, mutect2
- GRIA4 | c.487+44606A>G | Intron (SNP) | VAF 16/37 reads (43%) | called by muse, mutect2, varscan2
- GRID1 | c.*692A>G | 3'UTR (SNP) | VAF 42/170 reads (25%) | called by muse, mutect2, varscan2
- HADHB | c.110-2320_110-2310del | Intron (DEL) | VAF 34/90 reads (38%) | called by mutect2, pindel, varscan2
- HHIP | c.*5371C>G | 3'UTR (SNP) | VAF 6/79 reads (8%) | called by muse, mutect2
- HOXA7 | chr7:27152915 A>T | 3'Flank (SNP) | VAF 93/251 reads (37%) | called by muse, mutect2, varscan2
- KRTAP2-2 | c.*174C>T | 3'UTR (SNP) | VAF 8/100 reads (8%) | called by muse, mutect2
- LEKR1 | c.264-32266C>T | Intron (SNP) | VAF 99/215 reads (46%) | called by muse, mutect2, varscan2
- LMTK2 | c.*970T>C | 3'UTR (SNP) | VAF 47/100 reads (47%) | called by muse, mutect2, varscan2
- MAP2K5 | c.136-881T>C | Intron (SNP) | VAF 34/88 reads (39%) | called by muse, mutect2, varscan2
- MARF1 | chr16:15643357 C>A | 5'Flank (SNP) | VAF 7/52 reads (13%) | catalogued as rs768896489; called by muse, mutect2, varscan2
- MIR5195 | chr14:106851266 C>G | 5'Flank (SNP) | VAF 116/117 reads (99%) | catalogued as rs545752688; called by muse, mutect2, varscan2
- MYO1E | c.-88C>G | 5'UTR (SNP) | VAF 83/155 reads (54%) | catalogued as COSV55696289; called by muse, mutect2, varscan2
- MYO1H | c.*256C>A | 3'UTR (SNP) | VAF 30/67 reads (45%) | called by muse, mutect2, varscan2
- NDUFB5 | c.*1739T>C | 3'UTR (SNP) | VAF 24/422 reads (6%) | catalogued as rs1003110459; called by muse, mutect2
- NPL | c.230+271C>G | Intron (SNP) | VAF 35/222 reads (16%) | called by muse, mutect2, varscan2
- NRXN1 | c.*2781G>A | 3'UTR (SNP) | VAF 54/139 reads (39%) | called by muse, mutect2, varscan2
- OR56B1 | c.-33A>G | 5'UTR (SNP) | VAF 160/343 reads (47%) | called by muse, mutect2, varscan2
- OSBPL10 | c.2250+852T>A | Intron (SNP) | VAF 67/136 reads (49%) | called by muse, mutect2, varscan2
- PAX5 | c.*2141G>A | 3'UTR (SNP) | VAF 69/143 reads (48%) | called by muse, mutect2, varscan2
- PHACTR3 | c.*71C>G | 3'UTR (SNP) | VAF 122/291 reads (42%) | called by muse, mutect2, varscan2
- PITPNM2 | c.*2254A>G | 3'UTR (SNP) | VAF 31/71 reads (44%) | called by muse, mutect2, varscan2
- RCC1 | c.-261-773A>T | Intron (SNP) | VAF 36/37 reads (97%) | called by muse, mutect2, varscan2
- RUNX2 | c.*3502C>A | 3'UTR (SNP) | VAF 6/127 reads (5%) | called by muse, mutect2
- SCN1A | c.*1770A>T | 3'UTR (SNP) | VAF 55/102 reads (54%) | called by muse, mutect2, varscan2
- SHOX2 | c.347-688G>A | Intron (SNP) | VAF 28/159 reads (18%) | called by muse, mutect2, varscan2
- SNORD50B | chr6:85677395 C>T | 3'Flank (SNP) | VAF 34/89 reads (38%) | catalogued as rs766503797; called by muse, mutect2, varscan2
- SRD5A1 | c.294-6771T>G | Intron (SNP) | VAF 56/141 reads (40%) | called by muse, mutect2, varscan2
- ST6GAL1 | c.*2046A>T | 3'UTR (SNP) | VAF 66/180 reads (37%) | called by muse, mutect2, varscan2
- TMEM131 | c.-30C>T | 5'UTR (SNP) | VAF 39/80 reads (49%) | called by muse, mutect2, varscan2
- TMPO | c.*733C>A | 3'UTR (SNP) | VAF 31/68 reads (46%) | called by muse, mutect2, varscan2
- TNRC6C | c.*189G>A | 3'UTR (SNP) | VAF 54/123 reads (44%) | catalogued as rs1004031050; called by muse, mutect2, varscan2
- UBXN10 | c.*3153A>G | 3'UTR (SNP) | VAF 3/45 reads (7%) | called by muse, mutect2
- ZBTB24 | c.*3230G>T | 3'UTR (SNP) | VAF 17/74 reads (23%) | called by muse, mutect2, varscan2
- ZBTB39 | c.*1712C>G | 3'UTR (SNP) | VAF 52/114 reads (46%) | called by muse, mutect2, varscan2
- ZNF335 | chr20:45948024 del TG | 3'Flank (DEL) | VAF 168/441 reads (38%) | catalogued as rs1251433776; called by pindel, varscan2
- ZNF804B | c.-71G>A | 5'UTR (SNP) | VAF 4/77 reads (5%) | called by muse, mutect2
